Somatic mutation profile of tumor specimen 0DJPCT from CCDI case PBBXED, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 14.7 years (5,377 days).
Specimen 0DJPCT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0702f266-071a-436e-ac5c-ca46403a96c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJPCN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d04204d7-7c17-4cc6-9403-9611f22b7b8f

The open-access MAF lists 67 somatic variants for this specimen: 35 protein-altering or splice-affecting, 19 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 19, Intron 8, Nonsense Mutation 3, 5'UTR 2, 3'UTR 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP10 | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 125/894 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs369259498; called by muse, mutect2, varscan2
- CCDC85A | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 54/1282 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.556); catalogued as rs1250701844, COSV101339462; called by muse, mutect2
- CDH23 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 62/434 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs181449189; ClinVar: uncertain significance; called by muse, mutect2
- DENND2C | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 146/619 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.415); catalogued as rs554892827; called by muse, mutect2, varscan2
- ERMN | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 36/880 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV68075175; called by muse, mutect2
- HMCN1 | c.11357C>T p.T3786I | Missense Mutation (SNP) | VAF 101/754 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV54928193; called by muse, mutect2, varscan2
- KMT2D | c.6709C>T p.Q2237* | Nonsense Mutation (SNP) | VAF 44/495 reads (9%) | catalogued as rs1305346926, COSV56426006; called by muse, mutect2
- LPXN | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 65/505 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs202037573, COSV67716707; called by muse, mutect2, varscan2
- MAPK1 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 42/830 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53185671; called by muse, mutect2
- NLRP6 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 115/724 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs1180578843; called by muse, mutect2, varscan2
- PIK3CB | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 80/628 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56685948; called by muse, mutect2, varscan2
- PIP4K2A | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 123/903 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs1056061175; called by muse, mutect2, varscan2
- POGK | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 96/538 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs547734745; called by muse, varscan2
- SRMS | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 79/568 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.672); catalogued as rs761958111; called by muse, mutect2, varscan2
- TTN | c.97768G>A p.E32590K (on ENST00000591111; = p.E25166K on NM_003319.4) | Missense Mutation (SNP) | VAF 85/883 reads (10%) | PolyPhen possibly damaging (0.552); catalogued as rs892921331, COSV59873721; called by muse, mutect2
- WDR5 | c.304_306del p.L102del | In Frame Del (DEL) | VAF 57/389 reads (15%) | catalogued as rs766698031; called by pindel, varscan2
- XRN2 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs1009938328; called by muse, mutect2
- ZNF670 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 126/833 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs775463462, COSV63608267; called by muse, mutect2, varscan2
- ALPG | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 30/711 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2
- DELE1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 30/883 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); called by muse, mutect2
- EP300 | c.3988G>C p.D1330H | Missense Mutation (SNP) | VAF 141/922 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- EPG5 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- EXOC3L2 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2
- GTSE1 | c.2079G>C p.M693I | Missense Mutation (SNP) | VAF 106/695 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HELZ | c.3581A>G p.Y1194C | Missense Mutation (SNP) | VAF 93/668 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KANK4 | c.2340C>G p.I780M | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- KPNA7 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 56/418 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- KRTCAP3 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 61/1126 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- LRRC9 | c.2935C>T p.L979F | Missense Mutation (SNP) | VAF 32/830 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- OR5C1 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 85/604 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SF3B3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 56/832 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPEG | c.8788C>T p.Q2930* | Nonsense Mutation (SNP) | VAF 51/454 reads (11%) | called by muse, mutect2, varscan2
- TM4SF5 | c.276C>G p.F92L | Missense Mutation (SNP) | VAF 88/470 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TRPS1 | c.2284G>C p.E762Q (on ENST00000220888 / NM_001330599.2; = p.E775Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/953 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); called by muse, mutect2
- ZNF665 | c.1721C>G p.S574* (on ENST00000600412; = p.S639* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 45/366 reads (12%) | called by muse, mutect2, varscan2
- BHLHE23 | c.204G>A p.Q68= (on ENST00000370346; = p.Q84= on NM_080606.4) | Silent (SNP) | VAF 36/336 reads (11%) | catalogued as rs1432490189; called by muse, mutect2
- CLPB | c.249C>T p.L83= | Silent (SNP) | VAF 39/381 reads (10%) | catalogued as rs200845330, COSV53628020, COSV53632212, COSV99577898; ClinVar: likely benign; called by muse, mutect2
- CNTN6 | c.228C>T p.H76= | Silent (SNP) | VAF 60/772 reads (8%) | called by muse, mutect2
- CPNE1 | c.66C>T p.I22= (on ENST00000352393; = p.I27= on NM_003915.5) | Silent (SNP) | VAF 42/1230 reads (3%) | catalogued as rs977868519, COSV58290520; called by muse, mutect2
- DCHS1 | c.3792C>T p.F1264= | Silent (SNP) | VAF 54/652 reads (8%) | called by muse, mutect2
- DENND2C | c.195G>A p.E65= | Silent (SNP) | VAF 30/811 reads (4%) | catalogued as COSV67923469; called by muse, mutect2
- FLII | c.1884G>A p.K628= | Silent (SNP) | VAF 20/392 reads (5%) | called by muse, mutect2
- FNDC5 | c.189C>T p.I63= | Silent (SNP) | VAF 54/712 reads (8%) | called by muse, mutect2
- GPR132 | c.258C>T p.L86= | Silent (SNP) | VAF 40/355 reads (11%) | catalogued as COSV61677493; called by muse, mutect2, varscan2
- HHEX | c.786C>T p.G262= | Silent (SNP) | VAF 82/632 reads (13%) | catalogued as rs776889398, COSV51105915; called by muse, mutect2, varscan2
- HOXD1 | c.783G>A p.E261= | Silent (SNP) | VAF 48/597 reads (8%) | called by muse, mutect2
- NPTN | c.1020C>T p.L340= | Silent (SNP) | VAF 39/661 reads (6%) | catalogued as COSV54737134; called by muse, mutect2
- NRCAM | c.453A>G p.K151= (on ENST00000379028 / NM_001371124.1; = p.K145= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 36/656 reads (5%) | called by muse, mutect2
- PKDREJ | c.171C>T p.L57= | Silent (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- RGS22 | c.111C>T p.S37= | Silent (SNP) | VAF 24/714 reads (3%) | called by muse, mutect2
- SEMA7A | c.1191G>A p.L397= | Silent (SNP) | VAF 100/469 reads (21%) | catalogued as rs755037814; called by muse, mutect2, varscan2
- USP39 | c.1509C>T p.I503= | Silent (SNP) | VAF 24/801 reads (3%) | catalogued as rs1300415456; called by muse, mutect2
- ZFR2 | c.777G>A p.P259= | Silent (SNP) | VAF 45/345 reads (13%) | catalogued as rs751790337; called by muse, mutect2, varscan2
- ZXDC | c.2451C>T p.L817= | Silent (SNP) | VAF 18/591 reads (3%) | called by muse, mutect2
- ABTB1 | c.320+59G>A | Intron (SNP) | VAF 32/342 reads (9%) | catalogued as rs554708787; called by muse, mutect2
- AC022415.2 | c.*3229C>T | 3'UTR (SNP) | VAF 58/409 reads (14%) | catalogued as rs528480360; called by muse, mutect2, varscan2
- CSAG1 | c.*81C>G | 3'UTR (SNP) | VAF 61/213 reads (29%) | called by muse, mutect2
- DCHS2 | n.4224G>A | RNA (SNP) | VAF 49/670 reads (7%) | catalogued as COSV61769826; called by muse, mutect2
- MGAM | c.4619-11289C>T | Intron (SNP) | VAF 33/342 reads (10%) | called by muse, mutect2
- MXD3 | c.206+62C>G | Intron (SNP) | VAF 29/210 reads (14%) | called by muse, mutect2, varscan2
- NBEAL1 | c.305+30C>T | Intron (SNP) | VAF 46/323 reads (14%) | called by muse, mutect2, varscan2
- NUTF2 | c.271-39C>A | Intron (SNP) | VAF 43/318 reads (14%) | catalogued as COSV54647738; called by muse, mutect2, varscan2
- ROBO4 | c.2435+71G>A | Intron (SNP) | VAF 19/173 reads (11%) | catalogued as rs1017895693; called by muse, mutect2, varscan2
- SEPTIN9 | c.-28T>C | 5'UTR (SNP) | VAF 51/279 reads (18%) | catalogued as rs1489897047; called by muse, mutect2, varscan2
- SPTAN1 | c.4890+50C>T | Intron (SNP) | VAF 63/431 reads (15%) | catalogued as rs892898165; called by muse, mutect2, varscan2
- TBR1 | c.1190+26C>G | Intron (SNP) | VAF 54/1238 reads (4%) | called by muse, mutect2
- WIPI2 | c.-99G>A | 5'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
